Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A7C1, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A7C1-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIALUUID: 68C0AD64-6179-40B9-AAB8-6D0572D82432

DOB :
SEX : Male
PHONE : [REDACTED]

Referred By:

Anatomical Pathology

For further consultation on this report -

Page 1 of 2

Lab #:

CLINICAL NOTES

Ca stomach - radical gastrectomy

MACROSCOPIC DESCRIPTION

Three specimen containers received labelled [REDACTED]
The name and biopsy number on the cassettes supplied match those on the specimen request and the specimen containers.

1. The contents are labelled as "Distal gastrectomy double loop left gastric pedicle". A portion of stomach measuring 120x55x40mm with a 70mm stapled proximal resection margin and a 30mm stapled distal resection margin. A small amount of fatty tissue is adherent to the lesser curvature measuring up to 35mm from the serosa and a portion of omentum is adherent to the greater curvature measuring 190x180x30mm. On the mucosa of the lesser curvature is an ulcerated tumour measuring 30mm in diameter. On cross section the tumour does not appear to involve the muscularis propria. No other erosions or tumours are seen on the gastric mucosa. Blocks selected. a and b-proximal margin. c and d-distal margin. e and f-tumour. g-random greater curvature. h-lesser curvature nodes. i-greater curvature nodes. j, k-omentum.

2. The contents are labelled as "Gallbladder". A gallbladder measuring 70x30mm. The serosa of the gallbladder is smooth, the walls up to 5mm in thickness, and the mucosa is smooth. Several gallstones up to 4mm in maximum dimension are identified in the neck of the gallbladder. Representative sample processed in block 2a.

3. The contents are labelled as "Gallstones". Numerous black gallstones up to 5mm in maximum dimension and weighing approximately 4gms. No tissue is processed.

MICROSCOPIC DESCRIPTION

1. The sections confirm an ulcerated poorly differentiated gastric adenocarcinoma composed of pleomorphic epithelial cells showing little attempt at tubule formation. There is marked pleomorphism, numerous mitoses and there is evidence of degeneration within the

Tests Requested:

Anatomical Pathology

Collected

Page 1 of 2

DISCLAIMER: The contents of this report are intended only for the person or entity to which this is addressed and may contain confidential and privileged material. If you are not, or believe you may not be, the intended recipient, please advise immediately by phoning [REDACTED]

CSCF ICD-O-3
Adenocarcinoma, diffuse 8145/3
path
Adenocarcinoma NOS 8140/3
Site CSCF
path Fundus of stomach C16.1
Lesser curvature of stomach C16.5
9/29/13

[page 2 of 3]
DOB :
SEX : Male
PHONE : [REDACTED]

Referred By:

Anatomical Pathology

Collected :
Validated :
Printed :
File/Ref No. :

Anatomical Pathology

For further consultation on this report - Phone

Page 2 of 2

tumour. Tumour is invading the submucosa which is focally oedematous and is superficially present in the muscularis propria. There is a marked lichenoid inflammatory cell infiltrate surrounding the tumour.

A single focus of possible lymphatic permeation is noted deep to the tumour. There is no evidence of perineural space invasion however tumour is present in close proximity to neurovascular bundles. The tumour has an extensive lateral spread.

The adjacent gastric epithelium shows features of chronic gastritis with intestinal metaplasia and small lymphoid aggregates. Helicobacter pylori like organisms are not definitively identified in the surface and pit mucus.

Sections of the proximal and distal resection margin show no evidence of metastatic disease. None of the 23 lymph nodes examined contain tumour. Tumour is not seen within the omental fat.

2. Sections of gallbladder wall show a moderately thickened muscularis with fibrosis and scattered chronic inflammatory cells. There are no features of malignancy.

PATHOLOGIST'S OPINION

1. Distal gastrectomy. Ulcerated poorly differentiated adenocarcinoma, 30mm in diameter, extending into muscularis propria. One focus of possible lymphovascular space invasion; no evidence of lymph node (none out of 23 nodes), peritoneal or omental involvement.

2. Gallbladder. Mild chronic cholecystitis and cholelithiasis.

3. Gallstones. Black gallstones suggestive of pigment stones.

Pathologist:

SNOMED T#: 63
SNOMED M#: 81403

Per pathologic discrepancy form from the TSS, the TCSA tumor is a stomach, diffuse type, adenocarcinoma

Tests Requested:

Anatomical Pathology

Collected

Page 2 of 2

DISCLAIMER: The contents of this are intended only for the person or entity to which this is addressed and may contain confidential and privileged material. If you are not, or believe you may not be, the intended recipient, please advise immediately by phoning

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____

Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Adenocarcinoma (NOS)	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Adenocarcinoma - diffuse type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Subtype classification not specified in pathology report	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 478757cb-67ca-4451-9c0b-2aad66950e02 (TCGA-RD-A7C1.68C0AD64-6179-40B9-AAB8-6D0572D82432.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).